Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NF, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NF-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old with distal esophageal adenocarcinoma. Esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Esophagus." A 9 cm long, 5 cm in diameter segment of distal esophagus with attached 4 cm stomach and scant paraesophageal tissue. GE junction irregular with a 1.5 x 1.2 x 0.5 cm nodule with tan, ulcerated surface. Sectioning reveals that the lesion is 0.7 cm in full-thickness and appears not involving the muscularis propria, 0.7 cm from deep resection margin. The remaining esophagus with grey, smooth mucosa, 0.5 cm thick without discrete lesions. Gastric mucosa light brown, nodular. Wall 0.7 cm thick. Serosa unremarkable. Multiple possible lymph nodes identified in the scant periesophageal tissue.
1A - 1C. GE junction nodule.
1D - 1G. Remaining GE junction.
1H. Stomach with distal resection margin.
1I. Esophagus.
1J & 1K. Possible lymph nodes.
2. "Celiac lymph node." A 1.2 x 1 x 0.8 cm tan, firm soft tissue nodule with attached adipose tissue. Sectioning reveals tan, gelatinous cut surfaces.
3. "Spleen." 520 gram, 15 x 12 x 5 cm total spleen. Surface grey-brown with patchy thickening. Sectioning reveals a 2 x 2 x 1 cm subcapsular hemorrhagic area. Otherwise, the parenchyma is red, soft, homogeneous without discrete lesions. Hilar vessels unremarkable. A possible hilar lymph node identified.
3A. Parenchyma with overlying thickened capsule.
3B. Hemorrhagic area.
3C. Representative sections of parenchyma.
3D. Hilar structure with possible lymph nodes.
4. "Cervicoesophageal margin." A 1 cm long, 2 cm in diameter segment of esophagus with one end closed by suture.
4A. Open end.
4B. Closed end.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

If adenocarcinoma, is it arising in: Barrett's mucosa.

ICD-O-3
Adenocarcinoma NOS
8140/3
Site Esophagus, distal
thud @15.5
JCO 11/17/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Depth of invasion: Submucosa.

Number of positive lymph nodes/ total nodes: 1/3 (celiac)

Extranodal metastasis: Unknown.

Pattern of invasion: Both.

Esophageal and gastric resection margins involved; No.

Deep resection margin involved: No.

TNM classification: T1 N0 M1a (celiac node positive)

PROCEDURE:

VERIFIED BY:

1. Esophagus, resection: Invasive adenocarcinoma extending into the submucosa and arising in dysplastic Barrett's mucosa. Two lymph nodes negative for neoplasm. Negative gastric resection margin. Please see template.
2. Lymph node, celiac, resection: Metastatic esophageal adenocarcinoma involving one lymph node.
3. Spleen, resection: Subcapsular hemorrhage. One lymph node negative for neoplasm.
4. Margin, cervicoesophageal, excision: Negative for neoplasm.

I, _____, Ph.D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

HLA Discrepancy		
Only Synchronous Primary Noted		

Source: NCI Genomic Data Commons file 5effcd71-e901-41b7-9f29-23fb90bd3ba9 (TCGA-L5-A8NF.B30CC544-847F-454E-AF0D-0DE71547C8A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).